Gene-level copy-number profile of tumor specimen ALCH-ADJ4-TTP1-A from ALCHEMIST case ALCH-ADJ4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.1 years (25,255 days).
Specimen ALCH-ADJ4-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6b6569b2-8c9c-43ef-a4d5-bb029ac0eaac.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADJ4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/08af6a18-4613-48c9-8827-9e91b1a6e2bc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 4,075; copy number 2: 51,589; copy number 3: 2,349; copy number 4: 377; copy number 6: 2; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:149,003,062–149,028,662, 1 gene: PDIA4.
- chr10:46,370,759–46,382,626, 1 gene (within-gene range 0–2): AC244230.1.
- chr11:73,376,399–73,397,474, 2 genes: RELT, AP000763.4.
- chr13:19,863,858–19,865,048, 1 gene: AL355001.2.
- chr17:183,824–191,587, 1 gene: LINC02091.
- chr17:22,331,597–22,413,744, 2 genes: AC087575.1, FLJ36000.
- chr19:56,176,008–56,185,775, 1 gene: GALP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:36,213,200–36,235,608, 2 genes, copy number 7: AL162511.1, RN7SKP21.
- chr20:64,290,187–64,313,132, 2 genes, copy number 6: CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 4,075. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
